Gene-level copy-number profile of tumor specimen ALCH-B36D-TTP1-A from ALCHEMIST case ALCH-B36D, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 51.2 years (18,718 days).
Specimen ALCH-B36D-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8e481736-1f1e-45b2-a24a-1a4ad954e4bc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B36D-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,244 have no estimate.
https://portal.gdc.cancer.gov/files/b06aa1fb-cb4a-4371-b5f1-ba7a75a43871

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 164; copy number 1: 6,541; copy number 2: 47,757; copy number 3: 3,832; copy number 4: 59; copy number 5: 3; copy number 6: 16; copy number 7: 1; copy number 10: 5; copy number 13: 1.

Homozygous deletions (total copy number 0; autosomes only): 164 genes in 33 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:16,978,926–17,011,928, 3 genes (within-gene range 0–2): AL049569.1, ATP13A2, AL049569.3.
- chr1:43,978,943–43,996,528, 2 genes (within-gene range 0–2): B4GALT2, CCDC24.
- chr3:52,777,595–52,809,009, 2 genes: ITIH1, ITIH3.
- chr6:30,876,421–30,900,156, 2 genes: DDR1, MIR4640.
- chr7:128,830,406–128,859,274, 1 gene (within-gene range 0–2): FLNC.
- chr8:37,784,191–37,849,861, 2 genes: ADGRA2, BRF2.
- chr8:144,333,957–144,361,286, 4 genes (within-gene range 0–2): SLC52A2, TMEM249, AC233992.2, FBXL6.
- chr9:19,507,452–22,455,740, 73 genes (broad region; genes not listed).
- chr9:124,262,876–124,265,809, 1 gene (within-gene range 0–2): AL162724.1.
- chr9:125,372,325–125,372,766, 1 gene: AL627223.1.
- chr9:133,224,905–133,228,591, 1 gene: LCN1P1.
- chr11:67,266,473–67,286,556, 1 gene: GRK2.
- chr11:68,312,591–68,449,275, 1 gene: LRP5.
- chr12:132,565,071–132,566,425, 1 gene (within-gene range 0–2): AC131212.2.
- chr15:25,176,832–25,225,284, 27 genes (within-gene range 0–2): SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30.
- chr16:28,258,686–28,292,173, 1 gene: AC138904.3.
- chr16:28,284,885–28,292,064, 1 gene: AC138904.1.
- chr16:55,324,203–55,330,756, 1 gene (within-gene range 0–2): IRX6.
- chr16:66,908,122–66,945,096, 4 genes (within-gene range 0–2): CDH16, RRAD, CIAO2B, CES2.
- chr16:66,944,660–66,945,096, 1 gene (within-gene range 0–2): AC009084.3.
- chr16:83,929,796–83,931,223, 1 gene (within-gene range 0–2): AC009119.2.
- chr17:2,337,498–2,401,104, 5 genes (within-gene range 0–3): SGSM2, AC006435.3, AC006435.2, MNT, AC006435.1.
- chr17:75,818,815–75,844,552, 2 genes (within-gene range 0–2): AC087289.1, UNC13D.
- chr17:81,303,771–81,309,248, 1 gene: LINC00482.
- chr18:79,395,856–79,529,325, 6 genes: NFATC1, AC018445.3, AC018445.5, AC018445.1, AC018445.4, AC018445.2.
- chr19:42,351,131–42,351,205, 1 gene (within-gene range 0–2): MIR8077.
- chr20:32,443,059–32,608,893, 7 genes: NOL4L, AL034550.1, AL034550.3, AL034550.2, AL133343.2, NOL4L-DT, AL133343.1.
- chr21:43,053,191–43,076,943, 1 gene: CBS.
- chr21:44,328,944–44,339,402, 3 genes (within-gene range 0–2): AP001062.3, CFAP410, AP001062.1.
- chr21:45,478,266–45,573,365, 2 genes (within-gene range 0–2): MIR6815, SLC19A1.
- chr22:18,936,411–18,947,741, 1 gene (within-gene range 0–3): AC007326.5.
- chr22:36,286,847–36,286,907, 1 gene (within-gene range 0–2): MIR6819.
- chr22:46,112,749–46,113,768, 3 genes (within-gene range 0–1): MIRLET7A3, MIR4763, MIRLET7B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 26 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:112,707,498–112,846,239, 3 genes, copy number 5 (within-gene range 3–5): APC, CBX3P3, RNU6-482P.
- chr14:18,333,726–18,419,273, 4 genes, copy number 6: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr21:10,413,477–13,120,807, 12 genes, copy number 6: BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.
- chr21:43,092,956–43,107,570, 1 gene, copy number 7: U2AF1.
- chr21:43,159,066–43,162,277, 1 gene, copy number 13: AP001631.1.
- chr22:15,282,557–15,350,043, 5 genes, copy number 10: AP000542.3, AP000542.1, AP000542.2, ZNF72P, BNIP3P2.

Autosomal genes at a single copy (total copy number 1): 6,508. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
